Gene-level copy-number profile of specimen HCM-CSHL-1266-C20-85M from HCMI case HCM-CSHL-1266-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 34.7 years (12,684 days).
Specimen HCM-CSHL-1266-C20-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d8552c2b-2ab1-4eca-9625-1d632fa2554b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1266-C20-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,733 have no estimate.
https://portal.gdc.cancer.gov/files/0f31b5a3-8e80-4669-a93d-d4e80444d06c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 936; copy number 2: 6,343; copy number 3: 19,439; copy number 4: 19,917; copy number 5: 8,175; copy number 6: 1,205; copy number 7: 816; copy number 8: 1,166; copy number 9: 361; copy number 10: 7; copy number 11: 465; copy number 12: 59; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 893 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 9: CFHR3.
- chr3:57,078,943–57,942,304, 24 genes, copy number 9 (within-gene range 2–9): AC097358.2, IL17RD, AC097358.1, HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16.
- chr3:75,182,754–75,435,110, 13 genes, copy number 9: RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP.
- chr12:166,856–684,127, 16 genes, copy number 9 (within-gene range 7–9): AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455.
- chr12:911,736–1,788,674, 14 genes, copy number 9: RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14.
- chr12:4,097,451–4,615,302, 13 genes, copy number 9 (within-gene range 8–9): HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2.
- chr12:6,477,714–11,895,377, 278 genes, copy number 9 (broad region; genes not listed).
- chr13:68,861,284–114,337,626, 524 genes, copy number 11–12 (broad region; genes not listed).
- chr17:18,432,051–18,551,705, 10 genes, copy number 9–17 (within-gene range 6–17): KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
